Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7886, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7886-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Specimen Description

- A. Gallbladder
- B. Bile duct margin
- C. Pancreatic margin
- D. Whipple specimen (sent with tissue bank nurse)
- E. Para-aortic lymph node

Clinical Information

Pancreatic cancer

Diagnosis

- A. Gallbladder:
- Chronic cholecystitis, negative for malignancy
- B. Bile Duct Margin for Frozen Section:
- Chronic inflammation, negative for malignancy
- C. Pancreatic Margin:
- Negative for malignancy
- D. Pancreas (Whipple's Pancreaticoduodenectomy):
- Moderate to poorly-differentiated invasive pancreatic duct carcinoma
- Size approximately 6.0 cm, with invasion into peripancreatic adipose tissue and duodenal wall with ulceration of duodenal

[page 2 of 5]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

mucosa (pT3)

- Margins positive at uncinate process and superior and posterior pancreaticoduodenal soft tissue margins
- Positive for lymphovascular and perineural invasion
- Metastatic carcinoma in four of eleven lymph nodes (pN1)

E. Para-aortic Lymph Node:

- Reactive lymph node tissue, negative for malignancy

Gross Description

Received are specimens A to E. All requisitions and specimen containers are labelled with the patient's name. The cassettes and AP identifiers are labelled with the Surgical Number

A. The specimen consists of an unopened gallbladder, measuring 9.0 cm in length by 3.5 x 2.0 cm. The outer peritoneal surface is smooth, while the roughened liver bed area is unremarkable. There is a small defect in the wall with leakage of green bile. The cystic duct lymph node is not visible. The mucosal surface of the gallbladder has a dark green velvety appearance. The wall ranges in thickness from 0.2 cm up to 0.6 cm. No localized lesions can be identified. No gallstones are present. Four sections are taken and submitted in two cassettes.

B. The specimen consists of a fragment of soft tissue, measuring 0.5 cm, submitted in toto in one cassette.

Please Note: Specimen was originally rejected due to "does not have full Dr. name". It has since been corrected and returned.

C. The specimen consists of pancreatic margin, 0.8 x 0.8 x 0.1 cm, submitted in toto in one cassette.

[page 3 of 5]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

D. The specimen consists of a pancreatoduodenectomy specimen, with the segment of distal antrum and duodenum measuring 27.0 cm in length. There is a shallow indurated ulcerated area, 2.5 cm distal from the pyloric valve, measuring 1.8 x 1.0 cm. This appears to lie 1.5 cm proximal to the area of the ampulla of Vater. This indurated ulcer appears to be in continuity with an area tumorous induration in the attached head of pancreas. The head of pancreas measures 6.0 x 4.5 x 3.0 cm. The uncinate margin and pancreatic neck margin are identified and painted orange and blue respectively. The common bile duct can be identified at the superior surface of the pancreas, and continuity cannot be traced through the dense tumorous tissue in the head of pancreas. At the ampullary region, there is a nodular thickening lying beneath the mucosa, measuring approximately 1.8 x 1.0 x 1.0 cm. Part of the common bile duct can be identified, but the exact orifice is not clearly evident. Transverse sectioning of the head of pancreas reveals a firm craggy area beneath the area of duodenal ulceration, this tumorous zone is ill-defined, but measures approximately 2.5 x 1.5 x 2.5 cm. It appears to extend close to the uncinate margin and possibly extend into peripancreatic tissue in the upper pancreaticoduodenal area. The ulcerated duodenal wall is obscured.

Further sectioning reveals small firm lymph nodes in the vicinity of the common bile duct, the superior margin, and the pancreas as well as in the pancreatoduodenal region.

Sections are taken as follows:

- D1 Pancreatic neck margin.
- D2,D3 Two halves of the superior transverse section of pancreas.
- D4,D5 Two halves of next transverse section of pancreas.
- D6,D7 Two halves of transverse sections through mid zone of pancreas including uncinate margin.
- D8 Additional sections of uncinate margin.
- D9,D10 Two halves of transverse sections through inferior part of pancreas head.
- D11 Section to include proximal nodular area at ampulla.
- D12 Section to include distal part of nodular ampulla.
- D13 Proximal common bile duct margin.
- D14,D15 Lymph nodes around common bile duct.
- D16,D17 Lymph nodes from pancreaticoduodenal area.
- D18 Distal duodenal resection margin.
- D19 Perpendicular section of pyloric valve margin closest to area of ulceration in the proximal duodenum.

E. The specimen consists of a firm fragment of oval tissue, measuring 1.6 x 1.2 x 0.6 cm. The tissue has a homogeneous cut surface. The specimen is sectioned into three fragments and is submitted entirely in two cassettes.

[page 4 of 5]
Surgical Pathology Report

Accession Number: [REDACTED]

Collected Date: [REDACTED]

Pathologist: [REDACTED]

Received Date/Time: [REDACTED]

Frozen Section Diagnosis

FSB. Bile Duct Margin:

- Negative for malignancy.

FSC. Pancreatic Margin:

- Negative for malignancy.

Reported by [REDACTED]

Microscopic Description

A. The gallbladder shows chronic inflammation with mild irregularity of mucosal architecture. No cytologic atypia is present.

B. Sections after routine processing confirm the frozen section diagnosis. Only a small segment of bile duct tissue is present. The surface epithelium is partly denuded but residual epithelium shows no significant atypia and there is no malignancy in this fragment.

C. Sections after routine processing confirm the frozen section diagnosis.

D. There is a widespread invasive pancreatic duct adenocarcinoma that shows a varied morphology, ranging from well-defined angulated ductal structures through to areas where more solid sheets and small nodules and single cells with prominent nuclear pleomorphism can be seen. The carcinoma erodes the common bile duct and focal areas of ductal dysplasia are evident. Carcinoma is present in practically all of the sections taken. The extent of carcinoma thus exceeds the extent of gross induration and it is estimated to have a size of at least 6.0 cm. Furthermore, carcinoma shows extension beyond the pancreas into peripancreatic tissue predominantly at the superior margin of the pancreas and in the zone between pancreas and duodenum. Carcinoma also invades into and through muscularis propria of the duodenum and ulcerates the overlying duodenal mucosa. Carcinoma also focally involves the uncinate margin, and there are areas where carcinoma encroaches on the cauterized soft tissue margin at the superior and posterior pancreaticoduodenal area. There is prominent perineural invasion, and the section taken of the proximal common bile duct margin includes carcinoma with perineural growth at this resection edge.

There is prominent lymphovascular invasion in areas, and there is metastatic carcinoma in four of eleven lymph nodes.

The proximal gastric and distal duodenal margins are unremarkable. The sections of the ampulla of Vater show prominence of periductal glands and smooth muscle but no cytologic atypia or tumor.

[page 5 of 5]
ACB:

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

E. Sections show lymph node tissue with no evidence of metastatic disease.

Source: NCI Genomic Data Commons file 76a063c3-eb08-4c79-8e98-115915f2df01 (TCGA-IB-7886.5D0F6AE4-A2AD-40BF-A823-11D065D5B1F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).